Somatic mutation profile of tumor specimen BA2440D (aliquot aq-BA2440D) from BEATAML1.0 case 2263, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.5 years (27,933 days).
Specimen BA2440D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10a989dd-8b52-4b0e-94e5-4a379056afb7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2788D (Solid Tissue Normal), aliquot aq-BA2788D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88a22acb-8bc7-429b-b040-4de1d1070be7

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 10, Silent 7, Splice Site 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGPAT5 | c.784A>G p.I262V | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs773982882; called by muse, mutect2, varscan2
- CCDC141 | c.3845C>T p.T1282I | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs748086006, COSV55384350; called by muse, mutect2
- KCNH6 | c.224C>A p.P75Q | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.773); catalogued as COSV59001833; called by muse, mutect2, varscan2
- LRRC10 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs201257055, COSV64060229, COSV64060517; ClinVar: uncertain significance; called by muse, varscan2
- MDM1 | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 82/232 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV57444320; called by muse, mutect2, varscan2
- ANAPC1 | c.5365G>A p.A1789T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.9); PolyPhen benign (0); called by mutect2, varscan2
- C12orf42 | c.677G>A p.S226N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.078); called by muse, varscan2
- CACNA2D4 | c.2795T>G p.V932G | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by mutect2, varscan2
- CALR | c.816+1G>A p.X272_splice | Splice Site (SNP) | VAF 28/96 reads (29%) | called by muse, mutect2, varscan2
- FNDC3B | c.541A>C p.I181L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- LETMD1 | c.798C>A p.Y266* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
- NEMF | c.1024-1G>T p.X342_splice | Splice Site (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- RBM12B | c.1482A>C p.K494N | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ACSS1 | c.477G>A p.R159= | Silent (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- ARHGEF17 | c.556C>A p.R186= | Silent (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2
- CELSR2 | c.3141C>A p.G1047= | Silent (SNP) | VAF 4/35 reads (11%) | called by muse, varscan2
- MUC15 | c.24G>T p.L8= | Silent (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- SPATA4 | c.24A>G p.K8= | Silent (SNP) | VAF 3/29 reads (10%) | called by muse, varscan2
- TRIM2 | c.2221C>A p.R741= (on ENST00000437508; = p.R768= on NM_015271.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 3/22 reads (14%) | called by muse, varscan2
- ZBTB48 | c.274C>A p.R92= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV59840376; called by muse, mutect2, varscan2
